TCGA case TCGA-QQ-A5VD — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e4fb6a08-9d3f-4e62-85ce-7ba0dc03c8e2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 52 years; Vital status: Alive.

Diagnoses (1)
1. Leiomyosarcoma, NOS: ICD-O-3 morphology code: 8890/3; ICD-10 code: C49.9; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Site of resection or biopsy: Connective, subcutaneous and other soft tissues, NOS; Classification of tumor: primary; Age at diagnosis: 52.0 years (19,004 days); Year of diagnosis: 2011; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis present: No; Tumor depth descriptor: Superficial.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 1.2; Tumor length measurement: 2; Tumor width measurement: 1.6.

Follow-up (3 entries)
- Days to follow up: 639 days (1.7 years); Disease response: Tumor Free.
- Days to follow up: 940 days (2.6 years); Disease response: Tumor Free.
- Days to follow up: 1,129 days (3.1 years); Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-QQ-A5VD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 250 mg.
  Slide TCGA-QQ-A5VD-01A-02-TSB: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 65; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-QQ-A5VD-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-QQ-A5VD-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Conventional leiomyosarcoma; Leiomyo major vessel involvement: No Major Vessel Involvement; Margin status: Negative; Tumor total necrosis: 0% (no necrosis or no mention of necrosis); Disease multifocal indicator: No; Locoregional recurrence indicator: No; Metastatic disease confirmed: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Foot/ankle.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic length: 2.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,129 days; disease-specific survival: no event (censored), 1,129 days; disease-free interval: no event (censored), 1,129 days; progression-free interval: no event (censored), 1,129 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-QQ-A5VD-01A-21D-A32H-01): tumor purity 0.42, ploidy 1.87, whole-genome doublings 0.
